Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3583, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3583-01A (Primary Tumor).

Diagnosis:

Rectosigmoidal resection material with inclusion of a poorly differentiated mucinous adenocarcinoma of the colorectal type, 2.5 cm from the aboral resection margin with a maximum diameter of 8.5 cm and with infiltration of the perirectal fatty tissue and nine regional lymph node metastases. The tumor extends to within direct proximity of the circumferential resection margin. Tumor-free colon resection margins. Tumor-free mesenteric resection margin. Tubular adenoma of the colon mucosa with high-grade dysplasia and transition to an intramucosal adenocarcinoma (synonym according to WHO: high-grade intraepithelial neoplasia; according to UICC: pTis) and also diverticulosis coli.

Tumor stage: pT3 pN2 (9/34) pMX; G3 L1 V0, R1.

Source: NCI Genomic Data Commons file ea0547f8-0f48-4554-84df-010a856c9a0f (TCGA-AG-3583.51E08A42-6BD7-4228-8AC0-DD0A8EFF1E52.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).